Somatic mutation profile of tumor specimen 0DP6HW from CCDI case PBCDAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; Age at diagnosis: 14.8 years (5,392 days).
Specimen 0DP6HW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c8487f8-ef60-4fea-bf39-8c84fae87488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/876323cd-49b2-4f5f-948f-5bc04352b1e3

The open-access MAF lists 33 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 2, 5'UTR 1, RNA 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.011); catalogued as rs960558790; called by muse, mutect2
- EPHA5 | c.630T>G p.F210L | Missense Mutation (SNP) | VAF 119/940 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV56660394; called by muse, mutect2, varscan2
- GALNT12 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 53/1094 reads (5%) | catalogued as rs200303625, COSV66662720; called by muse, mutect2
- HTR3C | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 50/870 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs369321709, COSV59177853; called by muse, mutect2
- MPZ | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 42/861 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs573456055, COSV60667609; ClinVar: uncertain significance; called by muse, mutect2
- NRF1 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 70/849 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs776912751; called by muse, mutect2
- NUP160 | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 53/881 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs369156455; called by muse, mutect2
- RSBN1L | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 57/868 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV58506784; called by muse, mutect2
- SYNE1 | c.16111C>T p.R5371* (on ENST00000367255 / NM_182961.4; = p.R5300* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 142/1337 reads (11%) | catalogued as rs772587027, CM157849; called by muse, mutect2, varscan2
- TRPC7 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 93/652 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61457059; called by muse, mutect2, varscan2
- ANKRD9 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 34/393 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- CCSER2 | c.1110T>A p.N370K | Missense Mutation (SNP) | VAF 71/1092 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- KRTAP10-6 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- NEK4 | c.961A>T p.M321L | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- PEG3 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 33/617 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- PHTF2 | c.319C>T p.P107S (on ENST00000248550 / NM_001366089.1; = p.P69S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/840 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); called by muse, mutect2
- POLH | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 91/811 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SCN2A | c.5696C>T p.T1899M | Missense Mutation (SNP) | VAF 90/1326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIGLEC6 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 57/776 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ACAN | c.7209G>A p.E2403= (on ENST00000560601 / NM_001369268.1; = p.E2327= on NM_001135.3) | Silent (SNP) | VAF 102/1002 reads (10%) | catalogued as rs1567194241; called by muse, mutect2
- BEND3 | c.381C>T p.Y127= | Silent (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- CD164L2 | c.147G>A p.A49= | Silent (SNP) | VAF 77/548 reads (14%) | catalogued as rs561233778; called by muse, mutect2, varscan2
- GNB3 | c.150G>A p.T50= | Silent (SNP) | VAF 36/682 reads (5%) | catalogued as rs1382910777, COSV51830958; called by muse, mutect2
- KCNJ5 | c.312C>T p.F104= | Silent (SNP) | VAF 50/780 reads (6%) | catalogued as rs201217363; ClinVar: benign; called by muse, mutect2
- KIF27 | c.2847A>G p.L949= | Silent (SNP) | VAF 46/748 reads (6%) | called by muse, mutect2
- LRRTM2 | c.264T>C p.T88= | Silent (SNP) | VAF 52/740 reads (7%) | catalogued as rs1396966297; called by muse, mutect2
- SLC29A1 | c.495T>A p.A165= | Silent (SNP) | VAF 88/513 reads (17%) | catalogued as COSV57580035; called by muse, mutect2, varscan2
- SOX17 | c.504C>T p.G168= | Silent (SNP) | VAF 12/303 reads (4%) | called by muse, mutect2
- ZBP1 | c.1203T>C p.L401= | Silent (SNP) | VAF 48/1059 reads (5%) | called by muse, mutect2
- LINC02874 | n.506G>C | RNA (SNP) | VAF 37/599 reads (6%) | called by muse, mutect2
- PHKG2 | c.327-62G>A | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2
- PLEKHS1 | c.-123T>C | 5'UTR (SNP) | VAF 29/598 reads (5%) | called by muse, mutect2
- RPL26 | chr17:8377517 A>T | 3'Flank (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
